Somatic mutation profile of tumor specimen MP2PRT-PAVDUI-TMP1-A (aliquot MP2PRT-PAVDUI-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVDUI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,692 days).
Specimen MP2PRT-PAVDUI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98032d99-c2dd-4a75-bd17-b7c0254320e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDUI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDUI-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dd12cee-afaf-4de7-b09f-88e7582a74c7

The open-access MAF lists 16 somatic variants for this specimen: 16 protein-altering or splice-affecting.
By variant classification: Missense Mutation 14, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.4768C>T p.Q1590* | Nonsense Mutation (SNP) | VAF 55/415 reads (13%) | catalogued as rs1559395617; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 75/423 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763301017, COSV99712429; called by muse, mutect2, varscan2
- COX7B2 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs1269963751; called by muse, mutect2
- CXADR | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.316); catalogued as rs1386890888; called by muse, mutect2, varscan2
- FREM3 | c.5563G>A p.E1855K | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs774683246; called by muse, mutect2, varscan2
- GPHN | c.1580G>A p.R527H (on ENST00000315266 / NM_001377519.1; = p.R560H on NM_020806.5) | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1364702887; called by muse, mutect2
- NMUR1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 146/445 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs201056270, COSV100531844; called by muse, varscan2
- RYR1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 179/559 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139006437, COSV62099806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM46 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901672806; called by muse, mutect2, varscan2
- TTN | c.26963G>A p.R8988Q (on ENST00000591111; = p.R8061Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/257 reads (33%) | PolyPhen benign (0.376); catalogued as rs397517527; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- USH1G | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 177/449 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs771022122, COSV58883992; called by muse, mutect2, varscan2
- CHAT | c.367del p.T123Lfs*77 | Frame Shift Del (DEL) | VAF 84/259 reads (32%) | called by mutect2, pindel, varscan2
- EDF1 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- IGKV1OR2-108 | chr2:113406870 ATTCA>TT | Missense Mutation (DEL) | VAF 50/132 reads (38%) | called by pindel, varscan2*
- NCKAP1L | c.2441C>T p.A814V | Missense Mutation (SNP) | VAF 105/298 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SPCS3 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.041); called by muse, mutect2, varscan2
